Somatic mutation profile of tumor specimen TCGA-85-7843-01A (aliquot TCGA-85-7843-01A-11D-2122-08) from TCGA case TCGA-85-7843, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 50.2 years (18,353 days).
Specimen TCGA-85-7843-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3c23222-8f41-4304-b924-29fa1b6859e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-7843-10A (Blood Derived Normal), aliquot TCGA-85-7843-10A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3773dd60-94f6-4294-85fc-f0ace37f0cc5

The open-access MAF lists 246 somatic variants for this specimen: 191 protein-altering or splice-affecting, 51 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 165, Silent 51, Nonsense Mutation 14, Splice Site 6, Frame Shift Del 5, 5'Flank 2, Intron 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC005833.1 | c.1128G>T p.L376F | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated, low confidence (0.46); catalogued as COSV99363118; called by muse, mutect2, varscan2
- ADAMTS12 | c.809A>G p.Y270C | Missense Mutation (SNP) | VAF 59/205 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100711504; called by muse, mutect2, varscan2
- ADCY4 | c.2574C>A p.N858K | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as COSV100156763; called by muse, mutect2, varscan2
- ADGRB3 | c.4508G>A p.W1503* | Nonsense Mutation (SNP) | VAF 23/66 reads (35%) | catalogued as COSV99485349, COSV99486423; called by muse, mutect2, varscan2
- ADGRV1 | c.6145T>C p.F2049L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101316308; called by muse, mutect2, varscan2
- ANK3 | c.386A>G p.N129S | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV99781590; called by muse, mutect2, varscan2
- ANKK1 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV58274717; called by muse, mutect2, varscan2
- ANKRD11 | c.7148A>T p.H2383L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99970251; called by muse, mutect2
- AP3B2 | c.1261A>T p.M421L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.075); catalogued as COSV99916847; called by muse, mutect2, varscan2
- APPBP2 | c.656A>G p.K219R | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.678); catalogued as COSV99319816; called by muse, mutect2, varscan2
- ARHGAP17 | c.344T>G p.V115G | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV99253875; called by muse, mutect2, varscan2
- ARHGAP32 | c.5464G>T p.E1822* (on ENST00000310343 / NM_001378025.1; = p.E1473* on NM_014715.4) | Nonsense Mutation (SNP) | VAF 84/143 reads (59%) | catalogued as COSV100088702, COSV59854737; called by muse, mutect2
- ATP1B4 | c.695G>C p.G232A (on ENST00000218008 / NM_001142447.3; = p.G228A on NM_012069.5) | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99486461; called by muse, mutect2, varscan2
- ATXN10 | c.652T>G p.L218V | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs770644931, COSV99426625; called by muse, mutect2, varscan2
- BBS12 | c.659T>A p.L220Q | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.017); catalogued as COSV100045061; called by muse, mutect2, varscan2
- C1orf174 | c.697G>C p.D233H | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100220846; called by muse, mutect2, varscan2
- CABYR | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as COSV100510134; called by muse, mutect2, varscan2
- CCNB3 | c.3112A>T p.T1038S | Missense Mutation (SNP) | VAF 62/82 reads (76%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV99329555; called by muse, mutect2, varscan2
- CCSER1 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100394947; called by muse, mutect2, varscan2
- CD276 | c.4C>G p.L2V | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV100573415, COSV59204367; called by muse, mutect2
- CD44 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99555944; called by muse, mutect2, varscan2
- CEACAM1 | c.1378G>A p.A460T | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.503); catalogued as COSV99362524; called by muse, mutect2, varscan2
- CEP131 | c.89C>A p.S30Y | Missense Mutation (SNP) | VAF 62/91 reads (68%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.858); catalogued as COSV99488812; called by muse, mutect2, varscan2
- CGNL1 | c.3201+1G>A p.X1067_splice | Splice Site (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99848896; called by muse, mutect2
- CLIP1 | c.1057C>T p.L353F | Missense Mutation (SNP) | VAF 65/106 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100212202; called by muse, mutect2, varscan2
- CNNM4 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.563); catalogued as rs1435833388, COSV65661302; called by muse, mutect2, varscan2
- CNTN6 | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV63170808; called by muse, mutect2, varscan2
- CNTNAP4 | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 12/103 reads (12%) | catalogued as COSV100272677; called by muse, mutect2, varscan2
- CNTNAP5 | c.2059C>A p.L687M | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101443076; called by muse, mutect2
- CNTNAP5 | c.2539G>C p.E847Q | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.723); catalogued as rs770110326, COSV101443908, COSV70473101, COSV70484268; called by muse, mutect2, varscan2
- COL19A1 | c.2912G>A p.G971D | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59572189; called by muse, mutect2, varscan2
- CR2 | c.2452C>A p.P818T | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs1372788641, COSV100889686, COSV65508024; called by muse, mutect2, varscan2
- CSMD2 | c.4175A>T p.Q1392L | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.309); catalogued as COSV99593572; called by muse, mutect2, varscan2
- CT45A10 | c.358C>A p.Q120K | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100867550; called by muse, mutect2, varscan2
- DISC1 | c.2412T>A p.D804E | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100790647, COSV64109879; called by muse, mutect2, varscan2
- DLGAP1 | c.832G>T p.A278S | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs113585667, COSV100232973, COSV59845252; called by muse, mutect2, varscan2
- DNAH8 | c.9923T>C p.L3308S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100546684; called by muse, mutect2, varscan2
- DUS2 | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 26/76 reads (34%) | catalogued as COSV100732472, COSV100732627; called by muse, mutect2, varscan2
- EIPR1 | c.644G>C p.R215P | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101182229; called by muse, mutect2, varscan2
- ENPEP | c.315C>A p.H105Q | Missense Mutation (SNP) | VAF 65/128 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as COSV54458101, COSV99487992; called by muse, mutect2, varscan2
- ENPP3 | c.2171T>C p.M724T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV100717831; called by muse, mutect2, varscan2
- EPHA1 | c.803A>G p.Y268C | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV99314464; called by muse, mutect2, varscan2
- EPHA5 | c.1969G>T p.E657* | Nonsense Mutation (SNP) | VAF 37/94 reads (39%) | catalogued as COSV99900455; called by muse, mutect2, varscan2
- EYA2 | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.495); catalogued as rs1311747479, COSV100427169; called by muse, mutect2, varscan2
- F2 | c.479C>A p.P160H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100319641; called by muse, mutect2, varscan2
- FAH | c.365-1G>T p.X122_splice | Splice Site (SNP) | VAF 22/83 reads (27%) | catalogued as COSV99930458; called by muse, mutect2, varscan2
- FAM135B | c.2534T>G p.I845R | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99426298; called by muse, mutect2
- FAM135B | c.2378G>T p.G793V | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV99426301; called by muse, mutect2, varscan2
- FAM135B | c.365A>G p.Q122R | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.954); catalogued as COSV99357853; called by muse, mutect2, varscan2
- FAT3 | c.13406A>C p.N4469T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99968997; called by muse, mutect2, varscan2
- FBXL12 | c.706A>T p.T236S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99928097; called by muse, mutect2, varscan2
- FBXL13 | c.2019-1G>A p.X673_splice | Splice Site (SNP) | VAF 45/150 reads (30%) | catalogued as COSV100501969; called by muse, mutect2, varscan2
- FBXO40 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); catalogued as COSV57524359; called by muse, mutect2, varscan2
- FCRL2 | c.1055C>A p.A352D | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100829975; called by muse, mutect2, varscan2
- FXR1 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV99976596; called by muse, mutect2, varscan2
- FZD6 | c.1357C>T p.H453Y | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.943); catalogued as COSV100708463; called by muse, mutect2, varscan2
- GABRA2 | c.241T>A p.S81T | Missense Mutation (SNP) | VAF 45/76 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100734660; called by muse, mutect2, varscan2
- GDPD1 | c.251T>C p.V84A | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1312106041, COSV52385749; called by muse, mutect2, varscan2
- GHR | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 45/358 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as COSV50127582; called by muse, mutect2, varscan2
- GIN1 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV101204376; called by muse, mutect2, varscan2
- GPR142 | c.1383A>T p.E461D | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV100170948; called by muse, mutect2, varscan2
- GPR149 | c.952A>G p.T318A | Missense Mutation (SNP) | VAF 228/317 reads (72%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs758892226, COSV101078643; called by muse, mutect2, varscan2
- GPS1 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as rs1371357099, COSV100136109; called by muse, mutect2
- GRIK1 | c.2417T>A p.L806Q | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100517548; called by muse, mutect2, varscan2
- GRM8 | c.1696C>A p.R566S | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.241); catalogued as COSV58840197; called by muse, mutect2, varscan2
- GUCY1A1 | c.523C>T p.H175Y | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.625); catalogued as rs772353799, COSV56651822; called by muse, mutect2, varscan2
- HAUS1 | c.180G>C p.Q60H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV99959112; called by muse, mutect2, varscan2
- HCN1 | c.2170G>T p.A724S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.067); catalogued as rs141383188; called by muse, mutect2, varscan2
- HHIP | c.362G>A p.S121N | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99667656; called by muse, mutect2, varscan2
- HMGXB4 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.35); PolyPhen benign (0.057); catalogued as COSV99330214; called by muse, varscan2
- HOOK2 | c.1783G>T p.A595S | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.433); catalogued as COSV99317783; called by muse, mutect2
- HSPB8 | c.425A>T p.K142I | Missense Mutation (SNP) | VAF 45/73 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99931348; called by muse, mutect2, varscan2
- IDH3A | c.1090G>C p.D364H | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.553); catalogued as COSV99357606, COSV99357689; called by muse, mutect2, varscan2
- IFT172 | c.2047C>G p.Q683E | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99563035; called by muse, mutect2, varscan2
- IGKV1D-16 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); catalogued as rs753804851; called by muse, mutect2, varscan2
- IL18BP | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1429674126, COSV99474912; called by muse, mutect2, varscan2
- IMPA1 | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV99809070; called by muse, mutect2, varscan2
- INSRR | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.034); catalogued as COSV100693672; called by muse, mutect2, varscan2
- IQSEC3 | c.2577G>T p.M859I (on ENST00000538872 / NM_001170738.2; = p.M556I on NM_015232.1) | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.52); PolyPhen benign (0.324); catalogued as COSV100407496; called by muse, mutect2, varscan2
- IRF8 | c.814G>C p.G272R | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as COSV51899423, COSV99236747; called by muse, mutect2, varscan2
- IRX2 | c.654A>T p.E218D | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as rs1219381181, COSV100121860; called by muse, mutect2, varscan2
- KIF21B | c.3080T>A p.L1027Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100144945; called by muse, mutect2, varscan2
- KIF24 | c.2173G>A p.G725S | Missense Mutation (SNP) | VAF 69/399 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.564); catalogued as COSV99903465; called by muse, mutect2, varscan2
- KRT15 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV99563216; called by muse, mutect2, varscan2
- LAMP3 | c.292A>C p.S98R | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV99660706; called by muse, mutect2, varscan2
- LILRA5 | c.644A>G p.Y215C | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100007037; called by muse, mutect2, varscan2
- LRP3 | c.1438T>A p.C480S | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99472444; called by muse, mutect2
- MACIR | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1554237707, COSV100174771; called by muse, mutect2
- MAGEC1 | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); catalogued as COSV99596225; called by muse, mutect2, varscan2
- MAP2 | c.2984C>G p.T995S | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV52298469; called by muse, mutect2, varscan2
- MARCHF11 | c.1097G>A p.R366K | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV100198167; called by muse, mutect2, varscan2
- MCHR1 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as rs371577233; called by muse, mutect2, varscan2
- MMP16 | c.1552G>T p.E518* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | catalogued as COSV99689784; called by muse, mutect2, varscan2
- MPEG1 | c.273G>T p.Q91H | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.275); catalogued as COSV57092071, COSV99915844; called by muse, mutect2, varscan2
- MRTFB | c.863A>G p.H288R | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.3); catalogued as COSV100371655; called by muse, mutect2, varscan2
- MS4A1 | c.337-1G>C p.X113_splice | Splice Site (SNP) | VAF 45/74 reads (61%) | catalogued as COSV100619405, COSV61941753; called by muse, mutect2, varscan2
- MST1R | c.3574G>T p.V1192L | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770355605, COSV99619387; called by muse, mutect2, varscan2
- MTUS2 | c.2373G>T p.R791S | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101462318; called by muse, mutect2, varscan2
- MUC5B | c.6886C>A p.L2296M | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.912); catalogued as COSV101500631; called by muse, mutect2, varscan2
- MYCN | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV55257366, COSV55261865; called by muse, mutect2, varscan2
- NFATC3 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100285572; called by muse, mutect2, varscan2
- NLRP13 | c.2618+2T>A p.X873_splice | Splice Site (SNP) | VAF 11/26 reads (42%) | catalogued as COSV100738412; called by muse, varscan2
- NNMT | c.190T>A p.S64T | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.119); catalogued as COSV100248919; called by muse, mutect2, varscan2
- NPRL3 | c.475C>T p.R159C (on ENST00000611875 / NM_001077350.3; = p.R134C on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs769300436, COSV101302094; ClinVar: uncertain significance; called by muse, varscan2
- OR51I1 | c.512G>A p.C171Y | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs374675719; called by muse, mutect2
- OR51V1 | c.590T>C p.F197S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100343460; called by muse, mutect2, varscan2
- PALLD | c.427C>A p.R143S | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV54989245, COSV99825506; called by muse, mutect2, varscan2
- PANX3 | c.828T>A p.S276R | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV99421723; called by muse, mutect2, varscan2
- PCDH11X | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 63/94 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV100014044; called by muse, mutect2, varscan2
- PCDH11X | c.3043G>C p.E1015Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100014046; called by muse, mutect2, varscan2
- PCDH15 | c.4750A>G p.K1584E | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV100905355; called by muse, mutect2, varscan2
- PCDH15 | c.1500G>A p.M500I | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as COSV100225534; called by muse, mutect2, varscan2
- PCDH9 | c.1189G>T p.G397C | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60592874; called by muse, mutect2, varscan2
- PHF3 | c.1150G>C p.A384P | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.102); catalogued as COSV100013762; called by muse, mutect2, varscan2
- PITRM1 | c.1319C>T p.S440F | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99829425; called by muse, mutect2, varscan2
- PKHD1 | c.3229G>C p.G1077R | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV100584126; called by muse, mutect2, varscan2
- PPFIA1 | c.1343C>G p.S448* | Nonsense Mutation (SNP) | VAF 21/470 reads (4%) | catalogued as COSV99557883; called by muse, mutect2
- PPFIA1 | c.2174C>T p.S725F | Missense Mutation (SNP) | VAF 10/276 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as COSV99557886; called by muse, mutect2
- PRDM9 | c.1135G>T p.A379S | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV99690941; called by muse, mutect2, varscan2
- PRDM9 | c.1363G>C p.E455Q | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV99690943; called by muse, mutect2, varscan2
- PXDNL | c.4337G>T p.C1446F | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100685391, COSV99080577; called by muse, mutect2, varscan2
- QRFP | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.722); catalogued as COSV100551062; called by muse, mutect2, varscan2
- R3HDM4 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs537357318, COSV100846415; called by muse, mutect2, varscan2
- REG3G | c.49T>C p.C17R | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV99709622; called by muse, mutect2, varscan2
- RIC3 | c.897G>T p.K299N (on ENST00000309737 / NM_001206671.4; = p.K298N on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100112252; called by muse, mutect2, varscan2
- RIMBP2 | c.2107G>T p.A703S | Missense Mutation (SNP) | VAF 79/109 reads (72%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV99900133, COSV99901063; called by muse, mutect2, varscan2
- RUBCN | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1262994691, COSV56364390; called by muse, mutect2, varscan2
- RYR2 | c.6217T>A p.S2073T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.724); catalogued as COSV100772129; called by muse, mutect2, varscan2
- RYR2 | c.9878G>A p.G3293E | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV100772130; called by muse, mutect2, varscan2
- SAMSN1 | c.634G>T p.G212* | Nonsense Mutation (SNP) | VAF 49/100 reads (49%) | catalogued as COSV99582084; called by muse, mutect2, varscan2
- SCN2A | c.3779A>G p.K1260R | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99332894; called by muse, mutect2, varscan2
- SEC23A | c.79A>T p.S27C | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100305743; called by muse, mutect2, varscan2
- SENP6 | c.1325G>C p.S442T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100519448; called by muse, mutect2, varscan2
- SLC2A2 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as COSV100049466, COSV58586313, COSV58587256; called by muse, mutect2, varscan2
- SLC35A4 | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as COSV100021438; called by muse, mutect2, varscan2
- SLC39A1 | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV100135652; called by muse, mutect2, varscan2
- SLC43A3 | c.56A>T p.E19V | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100725244; called by muse, mutect2
- SLC43A3 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 12/150 reads (8%) | catalogued as COSV100725245; called by muse, mutect2
- SLIT3 | c.2344C>G p.L782V | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100269178; called by muse, mutect2, varscan2
- SMC4 | c.1226G>A p.S409N | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV100644107; called by muse, mutect2, varscan2
- SNX20 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as COSV56059498; called by muse, mutect2, varscan2
- SOHLH1 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV100040403; called by muse, mutect2, varscan2
- SPHKAP | c.1664C>A p.P555Q | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100764363; called by muse, mutect2, varscan2
- ST3GAL2 | c.189G>C p.E63D | Missense Mutation (SNP) | VAF 14/75 reads (19%) | PolyPhen benign (0); catalogued as COSV100735746; called by muse, mutect2, varscan2
- STAM2 | c.907G>C p.V303L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99813269; called by muse, mutect2, varscan2
- SUCNR1 | c.808C>G p.Q270E | Missense Mutation (SNP) | VAF 18/354 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV100751807; called by muse, mutect2
- SUN5 | c.1070T>A p.V357E | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100644881; called by muse, mutect2, varscan2
- SYNE1 | c.5395C>T p.H1799Y (on ENST00000367255 / NM_182961.4; = p.H1806Y on NM_033071.3) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs966234091, COSV99574407; called by muse, mutect2, varscan2
- TBX19 | c.1126A>C p.S376R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV100892391; called by muse, mutect2, varscan2
- TBX19 | c.1127G>T p.S376I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV100892392, COSV63197612; called by muse, mutect2, varscan2
- TBX3 | c.506G>T p.R169L | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs772182165, COSV57469865, COSV57472337; called by muse, mutect2, varscan2
- TCTN3 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as COSV99797418; called by muse, mutect2, varscan2
- TET2 | c.2125G>T p.E709* | Nonsense Mutation (SNP) | VAF 42/108 reads (39%) | catalogued as COSV54425546, COSV99484167; called by muse, mutect2, varscan2
- THOC1 | c.700C>G p.L234V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99863552; called by muse, mutect2, varscan2
- TNXB | c.13045C>A p.L4349M (on ENST00000647633; = p.L4102M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1481539135; called by mutect2, varscan2
- TNXB | c.9656G>A p.W3219* (on ENST00000647633; = p.W2972* on NM_019105.8 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/65 reads (31%) | catalogued as COSV100926512; called by muse, mutect2, varscan2
- TP53 | c.1051A>T p.K351* | Nonsense Mutation (SNP) | VAF 19/38 reads (50%) | catalogued as COSV52745104, COSV52944131; called by muse, mutect2, varscan2
- TP53INP2 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.134); catalogued as COSV100873704; called by muse, mutect2
- TRIP11 | c.2121A>C p.K707N | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.794); catalogued as COSV99971023; called by muse, mutect2, varscan2
- TRIP12 | c.4874G>T p.G1625V | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99390773; called by muse, mutect2, varscan2
- TTN | c.86306C>A p.P28769H (on ENST00000591111; = p.P21345H on NM_003319.4) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | PolyPhen possibly damaging (0.855); catalogued as COSV100623930, COSV59996205; called by muse, mutect2
- TYR | c.335G>A p.C112Y | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99634168; called by muse, mutect2, varscan2
- UBR5 | c.2278C>G p.L760V | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.899); catalogued as COSV99641897; called by muse, mutect2, varscan2
- USP34 | c.8302G>C p.E2768Q | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV68406255; called by muse, mutect2, varscan2
- UTRN | c.1283A>T p.Q428L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV100840230; called by muse, mutect2, varscan2
- VCAN | c.3703C>G p.L1235V | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as COSV99426831; called by muse, mutect2, varscan2
- VEPH1 | c.1128-2A>T p.X376_splice | Splice Site (SNP) | VAF 15/108 reads (14%) | catalogued as COSV100747872; called by muse, varscan2
- VEPH1 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV62875735; called by muse, mutect2, varscan2
- VWA2 | c.643A>T p.T215S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100073892; called by muse, mutect2, varscan2
- WDR27 | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.643); catalogued as rs73039194; called by muse, mutect2, varscan2
- YEATS2 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV100528175; called by muse, mutect2
- ZBTB11 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100465715; called by muse, mutect2, varscan2
- ZFHX4 | c.6892G>A p.E2298K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99266127; called by muse, mutect2, varscan2
- ZFP36L2 | c.887C>G p.A296G | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.037); catalogued as COSV99144090; called by muse, mutect2
- ZFPM2 | c.3263A>T p.E1088V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV101023387; called by muse, mutect2, varscan2
- ZFR | c.2841G>T p.M947I | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV99416353; called by muse, mutect2, varscan2
- ZNF385D | c.196C>G p.H66D | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99875870; called by muse, mutect2, varscan2
- ZNF438 | c.369A>C p.R123S | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100062474; called by muse, mutect2, varscan2
- ZNF441 | c.1634A>G p.Y545C | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.503); catalogued as COSV100777452; called by muse, mutect2, varscan2
- ZNF521 | c.3202G>T p.A1068S | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as COSV100831401, COSV64132210; called by muse, mutect2, varscan2
- ZNF98 | c.1625G>C p.G542A | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV100757571, COSV63333852, COSV63334526; called by muse, mutect2, varscan2
- ZNFX1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 100/371 reads (27%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.026); catalogued as rs776307103, COSV65574464; called by muse, mutect2, varscan2
- AMIGO1 | c.925del p.V309Cfs*2 | Frame Shift Del (DEL) | VAF 10/98 reads (10%) | called by mutect2, varscan2
- CASD1 | c.2093C>A p.S698* | Nonsense Mutation (SNP) | VAF 20/79 reads (25%) | called by muse, varscan2
- CASD1 | c.2101del p.A701Lfs*8 | Frame Shift Del (DEL) | VAF 18/84 reads (21%) | called by pindel, varscan2
- CCL3 | c.106A>T p.S36C | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GOLGA4 | c.5212_5231del p.I1738Lfs*3 | Frame Shift Del (DEL) | VAF 28/159 reads (18%) | called by mutect2, pindel
- IGHV1OR21-1 | c.148A>T p.S50C | Missense Mutation (SNP) | VAF 26/220 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- KAT2B | c.2035del p.A679Hfs*22 | Frame Shift Del (DEL) | VAF 54/183 reads (30%) | called by mutect2, pindel, varscan2
- NUMA1 | c.3916del p.V1306Wfs*10 | Frame Shift Del (DEL) | VAF 12/69 reads (17%) | called by mutect2, pindel, varscan2
- PPP6R1 | c.1079dup p.L361Afs*10 | Frame Shift Ins (INS) | VAF 7/41 reads (17%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.9546G>T p.V3182= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV101316309; called by muse, mutect2, varscan2
- ALOX12 | c.705T>C p.G235= | Silent (SNP) | VAF 31/55 reads (56%) | catalogued as COSV99278314; called by muse, mutect2, varscan2
- ALOX12 | c.798A>G p.K266= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV99278319; called by muse, mutect2
- ARHGAP32 | c.5466G>A p.E1822= (on ENST00000310343 / NM_001378025.1; = p.E1473= on NM_014715.4) | Silent (SNP) | VAF 81/138 reads (59%) | catalogued as COSV100088700; called by muse, mutect2
- BDKRB2 | c.753G>A p.L251= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV100021371; called by muse, mutect2, varscan2
- CARMIL1 | c.2868G>T p.P956= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100278537, COSV61518218; called by muse, mutect2, varscan2
- CCDC158 | c.936C>T p.N312= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as rs747319510, COSV101187335; called by muse, mutect2, varscan2
- CLDN2 | c.282C>A p.A94= | Silent (SNP) | VAF 42/71 reads (59%) | catalogued as COSV61020855; called by muse, mutect2, varscan2
- CSMD3 | c.4926C>G p.L1642= (on ENST00000297405 / NM_001363185.1; = p.L1538= on NM_052900.3) | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV99843212; called by muse, mutect2, varscan2
- DNAH7 | c.3360C>T p.S1120= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as rs199987634, COSV56771128; called by muse, mutect2, varscan2
- DRP2 | c.2364C>T p.I788= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs1178669967, COSV100872018; called by muse, mutect2, varscan2
- EEFSEC | c.732C>A p.T244= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV99631015; called by muse, varscan2
- EEFSEC | c.741A>T p.S247= | Silent (SNP) | VAF 40/81 reads (49%) | catalogued as COSV99631018; called by muse, varscan2
- FBXL19 | c.912G>A p.R304= | Silent (SNP) | VAF 8/109 reads (7%) | catalogued as rs199802404, COSV100609256; called by muse, mutect2
- GABRA3 | c.813C>G p.L271= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV100943205; called by muse, mutect2, varscan2
- GNL1 | c.321G>T p.P107= | Silent (SNP) | VAF 53/180 reads (29%) | catalogued as COSV100925439; called by muse, mutect2, varscan2
- GPR108 | c.480C>G p.V160= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs768050988, COSV99901489; called by muse, mutect2, varscan2
- HLTF | c.979C>T p.L327= | Silent (SNP) | VAF 89/398 reads (22%) | catalogued as COSV100027036; called by muse, mutect2, varscan2
- KALRN | c.301C>A p.R101= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99566498; called by muse, mutect2
- MCMDC2 | c.252C>G p.L84= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100552188, COSV100552231; called by muse, mutect2, varscan2
- NAALAD2 | c.1953G>A p.V651= | Silent (SNP) | VAF 30/154 reads (19%) | catalogued as COSV100428690; called by muse, mutect2, varscan2
- NNMT | c.189C>G p.G63= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as COSV100248918; called by muse, mutect2, varscan2
- NPHS2 | c.615C>T p.S205= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs778514784, COSV100858198; ClinVar: likely benign; called by muse, mutect2, varscan2
- NSFL1C | c.111G>T p.A37= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as COSV53795520, COSV99401546; called by muse, mutect2, varscan2
- OR2T33 | c.279T>A p.A93= | Silent (SNP) | VAF 57/193 reads (30%) | catalogued as COSV100532187; called by muse, mutect2, varscan2
- OR51E2 | c.117T>C p.F39= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV101211386; called by muse, mutect2, varscan2
- OR8U1 | c.489C>A p.T163= | Silent (SNP) | VAF 28/503 reads (6%) | catalogued as COSV100164058; called by muse, mutect2
- PASD1 | c.153T>C p.D51= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as COSV100949513, COSV64855318; called by muse, mutect2, varscan2
- PLEC | c.8193G>T p.L2731= (on ENST00000322810 / NM_201380.4; = p.L2621= on NM_000445.5) | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV100517470; called by muse, mutect2, varscan2
- POF1B | c.234C>G p.L78= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs1274393275, COSV99427182; called by muse, mutect2, varscan2
- PTPRE | c.603G>A p.K201= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV99618631; called by muse, mutect2, varscan2
- PTPRM | c.3861T>C p.N1287= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV100159361; called by muse, mutect2, varscan2
- RRP12 | c.1467C>T p.S489= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as rs775808485, COSV100213378; called by muse, mutect2, varscan2
- RSRP1 | c.60G>A p.S20= | Silent (SNP) | VAF 40/103 reads (39%) | catalogued as COSV99682697; called by muse, mutect2, varscan2
- SFMBT1 | c.1350C>T p.L450= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99966312; called by muse, mutect2, varscan2
- SIM1 | c.729C>A p.I243= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99492639; called by muse, mutect2, varscan2
- SLC13A3 | c.933G>A p.K311= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as COSV99287085; called by muse, mutect2, varscan2
- SLC45A1 | c.558C>T p.T186= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs773210009, COSV99239426; called by muse, varscan2
- SYNM | c.1926C>A p.I642= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100152958; called by muse, varscan2
- TEX14 | c.4308C>T p.I1436= (on ENST00000240361 / NM_001201457.2; = p.I1390= on NM_031272.5) | Silent (SNP) | VAF 21/138 reads (15%) | catalogued as rs1262814999, COSV99543130; called by muse, mutect2, varscan2
- TMEM147 | c.225C>T p.S75= | Silent (SNP) | VAF 31/196 reads (16%) | catalogued as rs1045077120, COSV99382935; called by muse, mutect2, varscan2
- TMEM169 | c.747G>A p.E249= | Silent (SNP) | VAF 34/128 reads (27%) | catalogued as COSV55265290; called by muse, varscan2
- TMEM175 | c.960G>A p.V320= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as rs1560503628, COSV99298085; called by muse, mutect2, varscan2
- TPSD1 | c.279C>A p.L93= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV99274057; called by muse, mutect2, varscan2
- UBR5 | c.717C>T p.S239= | Silent (SNP) | VAF 41/253 reads (16%) | catalogued as rs768814975, COSV55290584; called by muse, mutect2, varscan2
- VPS50 | c.879G>T p.V293= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as COSV99298440; called by muse, mutect2, varscan2
- WIZ | c.2643G>A p.P881= (on ENST00000673675 / NM_001371589.1; = p.P144= on NM_021241.3) | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs769755703, COSV54611804; called by muse, mutect2, varscan2
- ZMYM2 | c.321A>G p.A107= | Silent (SNP) | VAF 23/36 reads (64%) | catalogued as rs760817972, COSV101244001; called by muse, mutect2, varscan2
- ZNF184 | c.657G>A p.E219= | Silent (SNP) | VAF 81/225 reads (36%) | catalogued as COSV53004812, COSV99279940; called by muse, mutect2, varscan2
- ZNF638 | c.2524C>T p.L842= | Silent (SNP) | VAF 45/120 reads (38%) | catalogued as rs1048399829, COSV100039547; called by muse, mutect2, varscan2
- ZNF721 | c.1455C>T p.G485= (on ENST00000338977; = p.G497= on NM_133474.4) | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs371757675; called by muse, mutect2, varscan2
- CLN5 | chr13:76992002 G>T | 5'Flank (SNP) | VAF 10/18 reads (56%) | catalogued as COSV101080402; called by muse, varscan2
- DOCK8 | c.53+218C>G | Intron (SNP) | VAF 3/9 reads (33%) | catalogued as COSV101213690; called by muse, mutect2
- HAS3 | chr16:69118454 G>C | 3'Flank (SNP) | VAF 15/58 reads (26%) | catalogued as COSV99544601; called by muse, mutect2, varscan2
- VKORC1 | chr16:31095535 A>T | 5'Flank (SNP) | VAF 28/54 reads (52%) | catalogued as COSV100161822; called by muse, mutect2, varscan2
